Gene-level copy-number profile of tumor specimen TCGA-V1-A9OL-01A from TCGA case TCGA-V1-A9OL, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9OL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.4b46c07b-91f4-4b82-b9ef-df62b49e0283.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V1-A9OL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fc1df5c6-7c4a-4698-bec5-8c3c683d6513

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 11,887; copy number 2: 44,526; copy number 3: 2,910; copy number 4: 426; copy number 5: 13; copy number 6: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V1-A9OL-01A-11D-A41J-01): tumor purity 0.9, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:11,833,926–12,702,913, 1 gene (within-gene range 0–2): MIR3681HG.
- chr2:12,030,303–13,007,029, 9 genes: SNORD18, MIR3681, RNU6-843P, AC096559.1, AC009486.2, AC009486.1, TRIB2, MIR3125, AC064875.1.
- chr4:21,520,854–22,330,330, 7 genes (within-gene range 0–1): AC096576.7, AC096576.3, AC096576.1, AC096576.2, KCNIP4-IT1, AC096719.1, RNU6-420P.
- chr8:58,031,334–58,032,682, 1 gene: AC104350.1.
- chr10:87,751,512–88,259,372, 10 genes (within-gene range 0–1): ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1.
- chr16:72,782,885–73,891,871, 1 gene (within-gene range 0–1): ZFHX3.
- chr16:72,973,374–74,296,762, 18 genes (within-gene range 0–1): AC132068.1, AC002044.3, AC002044.1, AC002044.2, AC116667.1, HCCAT5, AC116667.2, AC140912.1, AC009033.1, LINC01568, AC092114.1, AC087565.2, AC087565.1, AC092128.1, AC138627.1, AC138627.2, AC009120.6, PPIAP49.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:6,731,080–6,780,246, 2 genes, copy number 6: LINC01713, BMP2.
- chr20:25,612,935–25,919,681, 13 genes, copy number 5 (within-gene range 1–5): NANP, ZNF337-AS1, RN7SL594P, MED28P7, ZNF337, AL031673.1, AL390198.1, VN1R108P, FAM182B, BSNDP1, AL390198.2, BSNDP2, CFTRP1.

Autosomal genes at a single copy (total copy number 1): 9,500. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
